Gene-level copy-number profile of tumor specimen TCGA-13-0717-01A from TCGA case TCGA-13-0717, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.9 years (20,042 days).
Specimen TCGA-13-0717-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a741d476-65cd-4424-9612-3118190d7bba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0717-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/80707fee-35fb-437b-8144-2de1f855d0e3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 12,413; copy number 2: 11,929; copy number 3: 23,759; copy number 4: 10,801; copy number 5: 421; copy number 6: 307; copy number 7: 176; copy number 9: 2; copy number 10: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 184 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,793,293–5,709,548, 91 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr4:15,604,381–15,743,582, 6 genes, copy number 10: FBXL5, FAM200B, AC114744.2, BST1, AC114744.1, AC005798.1.
- chr4:17,800,655–18,021,876, 4 genes, copy number 7: DCAF16, NCAPG, LCORL, KRT18P63.
- chr5:31,053,565–31,066,132, 2 genes, copy number 9: RPL19P11, AC026421.1.
- chr17:28,703,197–29,930,276, 65 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr17:29,883,006–30,236,002, 16 genes, copy number 7: AC104982.1, EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2, AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5, SLC6A4, AC104984.1.

Autosomal genes at a single copy (total copy number 1): 9,992. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
